Surgical pathology report (de-identified scan), TCGA case TCGA-J2-8192, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J2-8192-01A (Primary Tumor).

[page 1 of 5]
MRN

Name

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status

Time Received

Order Number

Results

Correction

Source of Specimen

- A. 4R #1 NODE - FS-
- B. 4R #2 NODE - FS-
- C. STATION 7 LYMPH NODE - FS-
- D. 4L #1 LYMPH NODE - FS-
- E. 4L #2 LYMPH NODE - FS-
- F. 4L #3 LYMPH NODE - FS-
- G. STATION #5-
- H. HILAR NODE #1-
- I. HILAR NODE #2-
- J. HILAR NODE #3-
- K. LEFT UPPER LOBE LUNG NONFS-
- L. LEFT UPPER LOBE LUNG FS-

FINAL DIAGNOSIS:

- A. 4R #1 NODE - FS-
LYMPH NODE, NO TUMOR SEEN.
- B. 4R #2 NODE - FS-
LYMPH NODE, NO TUMOR SEEN.
- C. STATION 7 LYMPH NODE - FS-
LYMPH NODE, NO TUMOR SEEN.
- D. 4L #1 LYMPH NODE - FS-
LYMPH NODE, NO TUMOR SEEN.
- E. 4L #2 LYMPH NODE - FS-
LYMPH NODE, NO TUMOR SEEN.
- F. 4L #3 LYMPH NODE - FS-
LYMPH NODE, NO TUMOR SEEN.
- G. STATION #5-
LYMPH NODE, NO TUMOR SEEN.

Prepared f

[page 2 of 5]
H. HILAR NODE #1-
LYMPH NODE, NO TUMOR SEEN.
I. HILAR NODE #2-
LYMPH NODE WITH METASTATIC ADENOCARCINOMA.
J. HILAR NODE #3-
LYMPH NODE, NO TUMOR SEEN.
K. LEFT UPPER LOBE LUNG NONFS-
INVASIVE CARCINOMA.

HISTOLOGIC TYPE: ADENOCARCINOMA.

HISTOLOGIC GRADE: 2/4.

TUMOR FOCALITY: UNIFOCAL.

TUMOR SIZE: 3.5 CM.

TUMOR SITE: LEFT UPPER LOBE.

VISCERAL PLEURA INVASION: NOT PRESENT.

ATELECTASIS/OBSTRUCTIVE PNEUMONITIS EXTENDING TO HILUM: NOT
SEEN.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

LARGE VESSEL INVASION: NOT SEEN.

2 OF 2 PERIBRONCHIAL NODES ARE POSITIVE FOR METASTATIC TUMOR.

LYMPH NODES INCLUDED IN ALL PARTS: NUMBER INVOLVED : 3
NUMBER EXAMINED: 12

TNM STAGE: pT2a, pN1, pMX.

INCIDENTAL MENINGOTHELIAL-LIKE NODULE.

SPECIMEN TYPE: LEFT UPPER LOBECTOMY.

NO TUMOR SEEN AT RESECTION MARGINS.

L. LEFT UPPER LOBE LUNG FS-
SEE PART K.

[page 3 of 5]
Signed Others

Frozen Section

A. LEFT UPPER LOBE LYMPH NODES: 4R#1, 4R#2, STATION 7, 4L#1, 4L#2, 4L#3 - NO TUMOR SEEN.

LEFT UPPER LOBE - ADENOCARCINOMA.

Case Clinical Information

LEFT UPPER LOBE MASS

Gross Description

A. Received in formalin labeled with the patient's name and "4R #1 node FS" are two yellow-tan fibroadipose soft tissue fragments measuring 0.7 x 0.4 cm. Wrapped and submitted in A1.

B. Received in formalin labeled with the patient's name and "4R #2 node FS" is a yellow-tan fibroadipose tissue measuring 1.5 x 1.0 cm. Wrapped and entirely submitted in B1.

C. Received in formalin labeled with the patient's name and "station 7 lymph node FS" are three yellow-tan fibroadipose tissue fragment measuring 0.7 x 0.5 cm. Wrapped and submitted in C1.

D. Received in formalin labeled with the patient's name and "4L #1 lymph node FS" is a yellow-brown fibroadipose tissue measuring 0.4 x 0.4 cm. Wrapped and submitted in D1.

E. Received in formalin labeled with the patient's name and "4L #2 lymph node FS" are two yellow-brown fibroadipose tissue fragment measuring 0.5 x 0.5 cm. Wrapped and submitted in E1.

F. Received in formalin labeled with the patient's name and "4L #3 lymph node FS" is a yellow-tan fibroadipose tissue fragment measuring 0.7 x 0.5 cm. Wrapped and submitted in F1.

G. Received in formalin labeled with the patient's name and "station #5" are three yellow-tan fibroadipose tissue fragments measuring 0.4 x 0.4 cm. Wrapped and submitted in G1.

H. Received in formalin labeled with the patient's name and "hilar node #1" is a dark brown adipose tissue fragment measuring 0.4 x 0.3 cm. Wrapped and submitted in H1.

I. Received in formalin labeled with the patient's name and "hilar node #2" is a yellow-tan fibroadipose tissue measuring 0.8 x 0.7 cm. Wrapped and submitted in I1.

J. Received in formalin labeled with the patient's name and

Prepared for

[page 4 of 5]
"hilar node #3" is a yellow-tan fibroadipose tissue measuring 0.4 x 0.3 cm. Wrapped and submitted in J1. [REDACTED]

K. Received in formalin labeled with the patient's name and "left upper lobe lung NONFS" is a left upper lobe lung weighing 150 grams and measuring 15 x 7 x 4.0 cm. The pleura is a gray-dark brown with a moderate anthracotic streaking and has the staple line along one of the edges inked in black. The pleura has a retracted area which is inked in red. The specimen is serially sectioned showing gray-tan nodule measuring 3.5 x 2.5 x 3.5 cm located 1.7 cm from the stapled inked resection margin and 0.1 cm from the red inked pleura. The remainder of the parenchyma is gray-brown and spongy. No other lesion is grossly identified. Represented as follows: Bronchial and vascular resection margin in K1; tumor in relation with the pleural retracted area represented in K2-K7; parenchyma to the black inked stapled resection margin = K8; parenchyma away from the lesion = K9; and potential lymph node from the hilum measuring 0.7 cm = K10. [REDACTED]s)

L. Received in formalin labeled with the patient's name and "left upper lobe FS" is a gray-tan frozen section tissue fragment measuring 1.5 x 1.2 cm. Entirely submitted in L1. [REDACTED]

[REDACTED]

Signed Supplemental

K. BLOCK K4 WAS SENT TO RESPONSE GENETICS FOR EGFR MUTATION AND EXPRESSION, ERCC1, RRM1, TS, KRAS, AND ALK BREAK APART FISH. THE RESULTS ARE AS FOLLOWS:

MARKER:	VALUE:	RESULTS:
EGFR EXPRESSION	9.64	HIGH EXPRESSION
ERCC1	1.75	HIGH EXPRESSION
RRM1	1.40	HIGH EXPRESSION
TS	2.02	LOW EXPRESSION
EGFR MUTATION	E19DEL	MUTATION
KRAS	WILD-TYPE	NO MUTATION
ALK BREAK APART FISH	NEGATIVE	NEGATIVE REARRANGEMENT

THE FULL REPORT FROM RESPONSE GENETICS IS ON FILE IN THE PATHOLOGY DEPARTMENT.

[REDACTED]

Procedure

Pre [REDACTED]

[REDACTED]

[page 5 of 5]
A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK
H&E X1
G. AA ROUTINE H&E X1 BLOCK
H&E X1
H. AA ROUTINE H&E X1 BLOCK
H&E X1
I. AA ROUTINE H&E X1 BLOCK
H&E X1
J. AA ROUTINE H&E X1 BLOCK
H&E X1
K. AA ROUTINE H&E X1 BLOCK.1
H&E X1
K. AA ROUTINE H&E X1 BLOCK.2
H&E X1
K. AA ROUTINE H&E X1 BLOCK.3
H&E X1
K. AA ROUTINE H&E X1 BLOCK.4
H&E X1
K. AA ROUTINE H&E X1 BLOCK.5
H&E X1
K. AA ROUTINE H&E X1 BLOCK.6
H&E X1
K. AA ROUTINE H&E X1 BLOCK.7
H&E X1
K. AA ROUTINE H&E X1 BLOCK.8
H&E X1
K. AA ROUTINE H&E X1 BLOCK.9
H&E X1
K. AA ROUTINE H&E X1 BLOCK.10
H&E X1
L. AA ROUTINE H&E X1 BLOCK
H&E X1

Prepared for

Source: NCI Genomic Data Commons file 0c4cfb37-1ef3-4782-8a37-92c3cc3e7828 (TCGA-J2-8192.AB6BB598-F1A2-4691-90C4-E8D63DEA8772.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).